Somatic mutation profile of tumor specimen 0DI200 from CCDI case PBBVER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.3 years (6,319 days).
Specimen 0DI200: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27d33954-e20f-4e2c-838d-942f3cbf962f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI1JT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/639f4cc7-9e46-4774-a9c3-d47ee4f4a5fd

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Intron 3, 5'UTR 2, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 27/926 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100007905; called by muse, mutect2
- CLU | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 334/826 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.035); catalogued as rs766667870, COSV100324114; called by muse, mutect2, varscan2
- KANK4 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 146/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776739426, COSV58093420; called by muse, mutect2
- LRRK1 | c.27dup p.S10Qfs*23 | Frame Shift Ins (INS) | VAF 98/248 reads (40%) | catalogued as rs1422179063; called by mutect2, varscan2
- TMEM214 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as rs200807930, COSV53193899; called by muse, mutect2, varscan2
- AASDH | c.926C>G p.T309S | Missense Mutation (SNP) | VAF 42/1245 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ADM5 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO7 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 316/852 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- POLR3E | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 126/307 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SLC30A9 | c.190_193del p.V64Sfs*31 | Frame Shift Del (DEL) | VAF 235/666 reads (35%) | called by mutect2, varscan2
- TBC1D8B | c.2404C>A p.L802I | Missense Mutation (SNP) | VAF 37/1186 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2
- ZKSCAN8 | c.701G>A p.W234* | Nonsense Mutation (SNP) | VAF 328/706 reads (46%) | called by muse, mutect2, varscan2
- ABCD1 | c.186G>A p.A62= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs782728047; called by muse, mutect2, varscan2
- CNTD1 | c.912C>T p.A304= | Silent (SNP) | VAF 18/491 reads (4%) | called by muse, mutect2
- DNAI1 | c.1725G>A p.P575= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs772459151, COSV54281496; called by muse, mutect2, varscan2
- FBXL7 | c.762C>T p.I254= | Silent (SNP) | VAF 87/208 reads (42%) | called by muse, mutect2, varscan2
- FBXL7 | c.1281C>T p.C427= | Silent (SNP) | VAF 108/339 reads (32%) | catalogued as COSV61653325; called by muse, mutect2, varscan2
- KCNA7 | c.858C>T p.F286= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- NCSTN | c.2019G>A p.L673= | Silent (SNP) | VAF 56/592 reads (9%) | called by muse, mutect2
- BBS2 | c.940+92G>A | Intron (SNP) | VAF 53/106 reads (50%) | catalogued as rs1172058642; called by muse, mutect2, varscan2
- BRD4 | c.2158+321G>A | Intron (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2
- DLG3 | c.1406-12T>A | Intron (SNP) | VAF 36/1059 reads (3%) | called by muse, mutect2
- GTF2F1 | c.-90C>T | 5'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, varscan2
- VSTM1 | c.-60C>T | 5'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
